Somatic mutation profile of tumor specimen TCGA-G7-6796-01A (aliquot TCGA-G7-6796-01A-11D-1961-08) from TCGA case TCGA-G7-6796, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 58.2 years (21,252 days).
Specimen TCGA-G7-6796-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b1d90c3-6099-4483-ac70-03f84e28e247.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G7-6796-10A (Blood Derived Normal), aliquot TCGA-G7-6796-10A-01D-1962-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97cd34c3-6eee-4863-9861-69fdd8197ecc

The open-access MAF lists 52 somatic variants for this specimen: 39 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 12, Frame Shift Ins 3, Nonsense Mutation 2, Frame Shift Del 2, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.3108A>C p.Q1036H (on ENST00000272895 / NM_173076.3; = p.Q718H on NM_015657.3) | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV55968936; called by muse, mutect2, varscan2
- ACOX3 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1027781163, COSV100712010; called by muse, mutect2, varscan2
- ADAP2 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs771539682, COSV58295708; called by muse, mutect2, varscan2
- ADAR | c.398T>A p.L133Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52718673; called by muse, mutect2, varscan2
- ALKBH5 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs750655723, COSV67687202; called by mutect2, varscan2
- APCDD1 | c.1136C>G p.A379G | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV62372881; called by muse, mutect2, varscan2
- ARID1A | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV61383999; called by muse, mutect2, varscan2
- BRCA1 | c.2731G>A p.G911R | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as COSV58790154, COSV58793155, COSV58795568; called by muse, mutect2, varscan2
- C12orf57 | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV57547301; called by muse, mutect2
- C2CD5 | c.1031A>G p.E344G | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV61726349; called by muse, mutect2, varscan2
- CACYBP | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV62879977, COSV62880558; called by muse, mutect2, varscan2
- CARMIL1 | c.3308C>A p.P1103H | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV61521286; called by muse, mutect2, varscan2
- CATIP | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as COSV56823774; called by muse, mutect2, varscan2
- CENPC | c.540G>C p.K180N | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as COSV56625095; called by muse, mutect2, varscan2
- DNAH5 | c.266A>T p.E89V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54241376; called by muse, mutect2, varscan2
- EXOC7 | c.1834A>T p.I612F (on ENST00000335146 / NM_001145297.4; = p.I530F on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV58037249; called by muse, varscan2
- FBXL6 | c.1307A>G p.Q436R | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as COSV57352789; called by muse, mutect2, varscan2
- IKBKB | c.826T>A p.W276R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60598815; called by muse, mutect2, varscan2
- KIN | c.155G>C p.R52T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV63158630; called by muse, mutect2, varscan2
- KRT85 | c.181T>C p.S61P | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV57737648; called by muse, mutect2, varscan2
- LMBRD1 | c.374A>G p.E125G | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV65298555; called by muse, mutect2, varscan2
- MCPH1 | c.763A>T p.I255F | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); catalogued as COSV60917157; called by muse, mutect2, varscan2
- MPZL1 | c.638A>C p.K213T | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV63257005; called by muse, mutect2, varscan2
- MSI2 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52363878; called by muse, mutect2, varscan2
- PPP2R1A | c.1514T>C p.I505T | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV59046774; called by muse, mutect2, varscan2
- RNF150 | c.1056C>G p.N352K | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as COSV60796175; called by muse, mutect2, varscan2
- RPL22 | c.246T>A p.Y82* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV52378666; called by muse, mutect2, varscan2
- SEC23B | c.301A>T p.I101L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as COSV52722348; called by muse, mutect2, varscan2
- SYCP3 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.796); catalogued as COSV57148242; called by muse, mutect2, varscan2
- SYNE1 | c.11407A>G p.T3803A (on ENST00000367255 / NM_182961.4; = p.T3788A on NM_033071.3) | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs756907616, COSV55047942; called by muse, mutect2, varscan2
- TNFSF10 | c.217A>G p.M73V | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53843938; called by muse, mutect2, varscan2
- USPL1 | c.3172A>C p.K1058Q | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV55001311; called by muse, mutect2, varscan2
- VAV1 | c.1618T>G p.F540V | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58388176; called by muse, mutect2, varscan2
- CAPRIN2 | c.880_881insCAG p.V293_V294insA | In Frame Ins (INS) | VAF 54/235 reads (23%) | called by mutect2, varscan2*
- CPNE9 | c.912dup p.D305* | Frame Shift Ins (INS) | VAF 19/99 reads (19%) | called by mutect2, pindel, varscan2
- DNAH8 | c.7188del p.E2396Dfs*46 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel
- PEAK1 | c.4853_4856del p.R1618Nfs*28 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- TEKT1 | c.558dup p.I187Yfs*16 | Frame Shift Ins (INS) | VAF 32/242 reads (13%) | called by mutect2, pindel, varscan2
- TRAF5 | c.1581_1582insC p.S528Lfs*12 | Frame Shift Ins (INS) | VAF 15/108 reads (14%) | called by mutect2, pindel, varscan2
- ABCC9 | c.4239C>T p.C1413= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV53979957; called by muse, mutect2, varscan2
- BEST1 | c.1728C>T p.A576= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV56446155; called by muse, mutect2, varscan2
- EDC4 | c.333G>A p.K111= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV54646860; called by muse, mutect2, varscan2
- FCRL4 | c.273A>G p.P91= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as COSV54864343; called by muse, mutect2, varscan2
- ITM2B | c.696A>G p.Q232= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs1007037150, COSV66035615; called by muse, mutect2, varscan2
- KLC4 | c.1818G>T p.R606= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV52437758; called by muse, varscan2
- MACF1 | c.5853A>T p.L1951= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV57133756; called by muse, mutect2, varscan2
- NPEPPS | c.1158A>G p.V386= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV59104221; called by muse, mutect2, varscan2
- RBM42 | c.1233G>A p.K411= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs1372886256, COSV52898562; called by muse, mutect2, varscan2
- SLC25A38 | c.102C>T p.G34= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV56195016; called by muse, mutect2, varscan2
- TMEM248 | c.405T>C p.H135= | Silent (SNP) | VAF 38/220 reads (17%) | catalogued as COSV58577975; called by muse, mutect2, varscan2
- ZNF132 | c.1617A>T p.G539= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV54235652; called by muse, mutect2, varscan2
- PLCE1 | c.1207-42855A>G | Intron (SNP) | VAF 57/151 reads (38%) | catalogued as COSV99596027; called by muse, mutect2, varscan2
